Gene-level copy-number profile of tumor specimen TCGA-B5-A11I-01A from TCGA case TCGA-B5-A11I, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 65.3 years (23,857 days).
Specimen TCGA-B5-A11I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.b23a0b07-9239-4207-9c01-2250c5b412dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A11I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07092492-b181-4d9e-902a-ef105bff6771

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 10,439; copy number 3: 11,063; copy number 4: 21,841; copy number 5: 12,357; copy number 6: 1,242; copy number 7: 2,065; copy number 8: 7; copy number 9: 172; copy number 10: 171; copy number 12: 204; copy number 14: 37; copy number 15: 45; copy number 17: 17; copy number 19: 40; copy number 24: 95; copy number 25: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A11I-01A-11D-A10L-01): tumor purity 0.73, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 795 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,146,203–151,348,027, 208 genes, copy number 9–24 (within-gene range 6–24) (broad region; genes not listed).
- chr3:168,858,659–182,692,285, 219 genes, copy number 10–12 (broad region; genes not listed).
- chr3:196,598,549–197,749,727, 37 genes, copy number 14 (within-gene range 5–14): AC092933.2, LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, AC011322.1, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922.
- chr6:11,183,298–11,644,343, 9 genes, copy number 10 (within-gene range 7–10): NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP.
- chr6:36,315,761–36,839,444, 20 genes, copy number 15: BNIP5, ETV7, ETV7-AS1, PXT1, KCTD20, RN7SL502P, STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2.
- chr8:139,727,725–140,458,579, 5 genes, copy number 9 (within-gene range 7–9): TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13.
- chr16:10,033,684–11,527,245, 50 genes, copy number 10–15 (within-gene range 5–15): AC133565.1, IMPDH1P11, AC022168.1, RN7SL493P, ATF7IP2, AC131649.1, AC131649.2, RNU6-633P, LINC01290, EMP2, AC027277.1, AC027277.2, TEKT5, AC007595.1, MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24, NUBP1, TVP23A, AC133065.2, AC133065.1, CIITA, DEXI, AC133065.3, CLEC16A, RPL7P46, AC007014.2, AC007014.1, AC007220.2, AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2.
- chr16:70,802,084–71,230,722, 4 genes, copy number 10 (within-gene range 2–10): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:74,274,234–80,035,872, 243 genes, copy number 9–25 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
